Somatic mutation profile of tumor specimen 0DUSSK from CCDI case PBCKPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.9 years (1,056 days).
Specimen 0DUSSK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac00f0bc-c1b9-46a3-92de-dd8beae5d7ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUSSG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31d5030b-6069-4d52-8133-49097afe9b68

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Nonsense Mutation 2, Frame Shift Del 2, 3'UTR 2, Splice Region 1, 3'Flank 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>G p.F1174L | Missense Mutation (SNP) | VAF 52/840 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- BRD2 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 61/906 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.195); catalogued as rs756721721, COSV66372254; called by muse, mutect2
- DGKI | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 24/697 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.468); catalogued as COSV55956361; called by muse, mutect2
- FRY | c.5930G>A p.R1977Q | Missense Mutation (SNP) | VAF 114/486 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.233); catalogued as COSV66578105; called by muse, mutect2, varscan2
- IFNA8 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 40/792 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs28383786; called by muse, mutect2
- KIAA1614 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as COSV62552252; called by muse, mutect2
- LMOD1 | c.1127C>A p.A376D | Missense Mutation (SNP) | VAF 55/989 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100939059; called by muse, mutect2
- NLRP7 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 59/317 reads (19%) | catalogued as COSV60171709; called by muse, mutect2, varscan2
- PFKFB4 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 40/528 reads (8%) | PolyPhen possibly damaging (0.511); catalogued as rs140464894; called by muse, mutect2
- SORCS1 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 18/628 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1382200269; called by muse, mutect2
- VPS18 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs1254884497, COSV55029219, COSV55029450; called by muse, mutect2
- AK5 | c.986C>A p.S329* (on ENST00000354567 / NM_174858.3; = p.S303* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 18/578 reads (3%) | called by muse, mutect2
- ARID1B | c.2873G>T p.G958V | Missense Mutation (SNP) | VAF 24/684 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BOD1L1 | c.1325-1G>T p.X442_splice | Splice Site (SNP) | VAF 64/1034 reads (6%) | called by muse, mutect2
- C1QC | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- CD81 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 17/431 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2
- COL11A2 | c.2012A>G p.E671G (on ENST00000341947 / NM_080680.3; = p.E564G on NM_080679.2) | Missense Mutation (SNP) | VAF 186/481 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CRACDL | c.2420del p.K807Rfs*47 | Frame Shift Del (DEL) | VAF 58/394 reads (15%) | called by mutect2, varscan2
- CRYBG3 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 23/618 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2
- CYP26B1 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 153/418 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DNAH14 | c.6737G>T p.R2246M (on ENST00000445597; = p.R2899M on NM_001367479.1) | Missense Mutation (SNP) | VAF 74/1440 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2
- GAB4 | c.1475C>A p.P492Q | Missense Mutation (SNP) | VAF 20/653 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GLUL | c.-12A>G | Splice Region (SNP) | VAF 144/515 reads (28%) | called by muse, mutect2, varscan2
- LRRC74B | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 107/749 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAMDC2 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 81/1267 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.113); called by muse, mutect2
- MMD | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 57/1350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MOCS1 | c.1200C>A p.F400L | Missense Mutation (SNP) | VAF 132/758 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); called by mutect2, varscan2
- NFATC1 | c.1860C>A p.N620K | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN4X | c.1280G>T p.W427L | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF3 | c.2507_2528del p.E836Vfs*11 | Frame Shift Del (DEL) | VAF 168/458 reads (37%) | called by mutect2, varscan2
- RXFP1 | c.72T>A p.D24E | Missense Mutation (SNP) | VAF 53/1016 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- SYT14 | c.1530C>A p.S510R | Missense Mutation (SNP) | VAF 54/2039 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- ZNF267 | c.1664A>C p.K555T | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- DNAH6 | c.1386G>A p.S462= | Silent (SNP) | VAF 87/1597 reads (5%) | catalogued as rs369526342; called by muse, mutect2
- GPR83 | c.924C>A p.L308= | Silent (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
- NOSTRIN | c.123G>T p.L41= | Silent (SNP) | VAF 193/875 reads (22%) | catalogued as COSV58324117; called by muse, mutect2, varscan2
- OR2G2 | c.900G>T p.V300= | Silent (SNP) | VAF 59/1216 reads (5%) | catalogued as COSV60740657; called by muse, mutect2
- OTOF | c.4608G>A p.Q1536= (on ENST00000272371 / NM_194248.3; = p.Q769= on NM_004802.4) | Silent (SNP) | VAF 28/504 reads (6%) | called by muse, mutect2
- ZNFX1 | c.1311G>T p.L437= | Silent (SNP) | VAF 62/812 reads (8%) | called by muse, mutect2
- BCL11A | chr2:60452627 G>A | 3'Flank (SNP) | VAF 277/742 reads (37%) | called by muse, mutect2, varscan2
- CDV3 | c.*248C>A | 3'UTR (SNP) | VAF 33/523 reads (6%) | called by muse, mutect2
- HPS4 | c.706+147G>T | Intron (SNP) | VAF 83/1008 reads (8%) | catalogued as COSV61102610; called by muse, mutect2
- PTGIS | c.*44G>T | 3'UTR (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
